MMRF case MMRF_1846 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/f8fcf871-c397-4817-aaec-e0e2bf08ea9a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.5 years (21,384 days); ISS stage: I; Days to last known disease status: 1,093 days (3.0 years); Days to last follow up: 1,093 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 116 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 28 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 28 days; Days to treatment end: 116 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 119 days; Days to treatment end: 119 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 145 days; Days to treatment end: 186 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 145 days; Days to treatment end: 168 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 190 days; Days to treatment end: 190 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 191 days; Days to treatment end: 191 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 317 days; Days to treatment end: 561 days (1.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 575 days (1.6 years); Days to treatment end: 833 days (2.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 834 days (2.3 years); Days to treatment end: 885 days (2.4 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 885 days (2.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -11 (ECOG 1): M Protein 3.77 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 46.4 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 82 µmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 10.2 g/dL; Glucose 4.8 mmol/L; C-Reactive Protein 0.3 mg/dL.
- Day 84 (ECOG 0): M Protein 1.43 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.09 mg/dL; Immunoglobulin G 18.3 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 12.2 ×10⁹/L; Absolute Neutrophil 9.5 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 78 µmol/L; Calcium 2.21 mmol/L; Albumin 39 g/L; Total Protein 7.5 g/dL; Glucose 5.8 mmol/L.
- Day 168 (ECOG 0): M Protein 1.14 g/dL; Immunoglobulin G 17.9 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.18 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.15 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 86 µmol/L; Calcium 2.19 mmol/L; Albumin 42 g/L; Total Protein 7.8 g/dL; Glucose 4.9 mmol/L.
- Day 259 (ECOG 0): M Protein 4.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.35 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 2.07 g/L; Immunoglobulin M 0.8 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 68 µmol/L; Calcium 2.27 mmol/L; Albumin 40 g/L; Total Protein 7.3 g/dL; Glucose 5.2 mmol/L.
- Day 343 (ECOG 0): M Protein 5.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.59 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 0.99 g/L; Immunoglobulin M 0.62 g/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 71 µmol/L; Calcium 2.13 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 4.5 mmol/L.
- Day 477 (ECOG 0): M Protein 5.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.63 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 1.89 g/L; Immunoglobulin M 0.43 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 67 µmol/L; Calcium 2.16 mmol/L; Albumin 39 g/L; Total Protein 7.1 g/dL; Glucose 4.9 mmol/L.
- Day 561 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 10.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.9 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 2.63 g/L; Immunoglobulin M 0.44 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 265 ×10⁹/L; Creatinine 74 µmol/L; Calcium 2.06 mmol/L; Albumin 35 g/L; Glucose 5.9 mmol/L.
- Day 652 (ECOG 0): M Protein 5.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.4 mg/dL; Immunoglobulin G 15.5 g/L; Immunoglobulin A 3.68 g/L; Immunoglobulin M 0.69 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 276 ×10⁹/L; Creatinine 67 µmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 7.6 g/dL; Glucose 5.2 mmol/L.
- Day 743 (ECOG 0): M Protein 4.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.51 mg/dL; Immunoglobulin G 14.8 g/L; Immunoglobulin A 4.39 g/L; Immunoglobulin M 0.63 g/L; Hemoglobin 8.68 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 280 ×10⁹/L; Creatinine 74 µmol/L; Calcium 2.26 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 5.6 mmol/L.
- Day 834 (ECOG 0): M Protein 3.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 4.22 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 72 µmol/L; Calcium 2.15 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 5.4 mmol/L.
- Day 918 (ECOG 0): M Protein 4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.86 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 3.99 g/L; Immunoglobulin M 0.43 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 266 ×10⁹/L; Creatinine 71 µmol/L; Calcium 2.15 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 5 mmol/L.
- Day 1,009 (ECOG 0): M Protein 4.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 13.4 g/L; Immunoglobulin A 4.26 g/L; Immunoglobulin M 0.48 g/L; Hemoglobin 9.05 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 277 ×10⁹/L; Creatinine 78 µmol/L; Calcium 2.32 mmol/L; Albumin 44 g/L; Total Protein 7.8 g/dL; Glucose 5.4 mmol/L.
- Day 1,093 (ECOG 0): M Protein 3.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.21 mg/dL; Immunoglobulin G 14 g/L; Immunoglobulin A 4.43 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 5.77 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 293 ×10⁹/L; Creatinine 78 µmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 7.6 g/dL; Glucose 4.5 mmol/L.

Other clinical attributes
- Day -11: Weight: 83 kg; Height: 174 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1846_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -11 days.
- Sample MMRF_1846_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -11 days.
